Somatic mutation profile of tumor specimen TCGA-DX-AB2L-01A (aliquot TCGA-DX-AB2L-01A-32D-A417-09) from TCGA case TCGA-DX-AB2L, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 35.5 years (12,974 days).
Specimen TCGA-DX-AB2L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec6534a0-af58-418d-a023-ebfddc17edd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2L-10A (Blood Derived Normal), aliquot TCGA-DX-AB2L-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5d32ae8-6f31-439b-8ba3-39e6fb8f7c91

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.8288G>T p.G2763V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101316660; called by muse, mutect2
- DDX55 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2
- LY6G6D | c.186G>T p.V62= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV101010855; called by muse, mutect2
